Somatic mutation profile of tumor specimen TARGET-20-PARZMZ-03A (aliquot TARGET-20-PARZMZ-03A-01D) from TARGET case TARGET-20-PARZMZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (985 days).
Specimen TARGET-20-PARZMZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f23d577-f81d-4a31-8d96-1af8e067b142.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZMZ-14A (Bone Marrow Normal), aliquot TARGET-20-PARZMZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f66d4324-66e9-43ef-a4a7-8ed42a9c3e34

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.33); called by muse, mutect2, varscan2
